Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5792, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5792-01A (Primary Tumor).

TCGA-CH-5792

Diagnosis

Multifocal, acinar adenocarcinoma of the prostate with carcinoma foci on both sides, both in the apical and in the basal zone of the organ. In the region of the largest carcinoma focus is a left dorsoperipheral spread across the organ with infiltration of the periprostatic tissue. The outer areas of the resected material are tumor-free in the parts that can be visualized.

Tumor volume overall about 7 cm.

The follow-up resection material, the pelvic lymph nodes and seminal vesicles are tumor-free.

Tumor stage pT3a pN0, Gleason score 4+5.

Source: NCI Genomic Data Commons file 1d7926ad-040d-498e-b3fb-14b318ea3d53 (TCGA-CH-5792.72DE5993-CAD1-4BA0-9EA5-C545799A2F6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).